Somatic mutation profile of tumor specimen 0DG9FV from CCDI case PBBSXR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (5,975 days).
Specimen 0DG9FV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 981fb1bd-8b25-49cf-a333-5c9d492ba673.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG9FQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46a4b8f3-97a7-4185-8f53-83873c4a65d2

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 327/1016 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, varscan2
- DSCAM | c.934+1G>A p.X312_splice | Splice Site (SNP) | VAF 32/276 reads (12%) | catalogued as COSV68021194, COSV68025747; called by muse, varscan2
- DPYSL3 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, varscan2
- RNF123 | c.628T>C p.S210P | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SAT1 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- ANO7 | c.471+47C>T | Intron (SNP) | VAF 19/149 reads (13%) | called by mutect2, varscan2
